Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4693, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4693-01A (Primary Tumor).

FINAL DIAGNOSIS**PART 1: BONE, RIB, EXCISION:**

- A. FIBROCARILAGINOUS TISSUE WITH NO SPECIFIC PATHOLOGIC CHANGES.
- B. FRAGMENT OF BONE (GROSS EXAMINATION ONLY).

PART 2: KIDNEY, LEFT, RADICAL NEPHRECTOMY -

-
- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE WITH SARCOMATOID FEATURES, LARGE AREAS OF NECROSIS AND HEMORRHAGE (See synoptic).
- B. FUHRMAN NUCLEAR GRADE IS 4 of 4.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 13.0 cm.
- D. RENAL SINUS FAT IS INVOLVED BY CARCINOMA.
- E. THE NEOPLASM INVADES THROUGH THE RENAL CAPSULE, EXTENDS INTO THE PERIRENAL FAT AND IS LOCATED IN CLOSE PROXIMITY TO ADRENAL GLAND.
- F. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- G. ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- H. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- I. THE NON-NEOPLASTIC KIDNEY SHOWS CHANGES DUE TO PROXIMITY THE TUMOR.
- J. HISTOLOGICALLY UNREMARKABLE ADRENAL GLAND IS NOT INVOLVED BY CARCINOMA.
- K. TNM STAGE: pT3a N0 MX.

PART 3: LYMPH NODES, PERIAORTIC, EXCISION:

NO CARCINOMA SEEN IN FIVE LYMPH NODES EXAMINED (0/5)

Source: NCI Genomic Data Commons file 28917481-d22a-4553-bf4c-20dec98e74de (TCGA-B0-4693.A99C7ECF-6B88-4E24-BDF1-1C109EC20344.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).